Somatic mutation profile of tumor specimen MMRF_2054_1_BM_CD138pos (aliquot MMRF_2054_1_BM_CD138pos_T1_KHS5U_L08104) from MMRF case MMRF_2054, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.6 years (23,248 days).
Specimen MMRF_2054_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e7512f5a-6783-4e91-a50f-ff75c3c31e91.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2054_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2054_1_PB_Whole_C2_KHS5U_L08105; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5023aac6-b508-4285-86d2-654c39810dfd

The open-access MAF lists 113 somatic variants for this specimen: 46 protein-altering or splice-affecting, 20 silent, 47 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, 3'UTR 27, Silent 20, Intron 9, 5'UTR 4, 5'Flank 4, 3'Flank 3, Frame Shift Del 2, Splice Region 1, Splice Site 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 26/50 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANKS6 | c.2502C>A p.N834K | Missense Mutation (SNP) | VAF 82/254 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV62051751; called by muse, mutect2, varscan2
- DENND2C | c.1988G>A p.R663Q (on ENST00000393274 / NM_001256404.2; = p.R606Q on NM_198459.4) | Missense Mutation (SNP) | VAF 76/150 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746690091, COSV67923684; called by muse, mutect2, varscan2
- IGHV2-70 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs377473012; called by muse, varscan2
- IGHV2-70 | c.65C>T p.T22I | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs566067300; called by muse, varscan2
- IGHV2-70D | c.74A>G p.E25G | Missense Mutation (SNP) | VAF 45/80 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1474906953; called by muse, varscan2
- IGKV4-1 | c.171C>G p.N57K | Missense Mutation (SNP) | VAF 69/70 reads (99%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.772); catalogued as rs375642722; called by muse, mutect2, varscan2
- KIF6 | c.639G>A p.E213= | Splice Region (SNP) | VAF 4/62 reads (6%) | catalogued as rs1202396327; called by muse, mutect2
- LRRC8E | c.1253G>A p.R418Q | Missense Mutation (SNP) | VAF 137/245 reads (56%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs1008478167; called by muse, mutect2, varscan2
- NPAP1 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.101); catalogued as rs759520625, COSV100274550; called by muse, mutect2, varscan2
- NRG1 | c.1322C>G p.T441R (on ENST00000405005 / NM_013964.5; = p.T446R on NM_013956.5) | Missense Mutation (SNP) | VAF 111/233 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.945); catalogued as COSV99828055; called by muse, mutect2, varscan2
- PCDHB1 | c.648C>A p.D216E | Missense Mutation (SNP) | VAF 123/167 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1323608919, COSV60633376; called by muse, mutect2, varscan2
- PTPRK | c.4115C>T p.T1372M (on ENST00000368215 / NM_001291984.2; = p.T1373M on NM_002844.4) | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754096532, COSV63894614; called by muse, mutect2, varscan2
- RALGAPA1 | c.362C>A p.S121Y | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51883219; called by muse, mutect2, varscan2
- RELA | c.1586C>T p.S529L | Missense Mutation (SNP) | VAF 13/245 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as COSV58013805; called by muse, mutect2
- SP3 | c.1997A>G p.D666G | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59465793; called by muse, varscan2
- TENM4 | c.2296G>A p.E766K | Missense Mutation (SNP) | VAF 53/151 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs760037052; called by muse, mutect2, varscan2
- TOGARAM2 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 64/137 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs757201206; called by muse, mutect2, varscan2
- ZNF845 | c.797C>G p.T266S | Missense Mutation (SNP) | VAF 104/336 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.594); catalogued as COSV72004282; called by muse, mutect2, varscan2
- C7orf25 | c.853A>G p.K285E | Missense Mutation (SNP) | VAF 61/114 reads (54%) | SIFT tolerated (0.78); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CDR1 | c.625T>G p.S209A | Missense Mutation (SNP) | VAF 551/560 reads (98%) | SIFT tolerated (0.77); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CREBBP | c.3179_3180del p.K1060Rfs*6 | Frame Shift Del (DEL) | VAF 77/186 reads (41%) | called by mutect2, pindel, varscan2
- CYLC1 | c.1271dup p.D425Gfs*2 | Frame Shift Ins (INS) | VAF 25/28 reads (89%) | called by mutect2, varscan2
- FLNC | c.3229G>T p.V1077L | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- GALNT17 | c.1775C>T p.T592I | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- HDAC7 | c.443_449del p.F148Cfs*10 (on ENST00000427332; = p.F187Cfs*10 on NM_015401.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 12/112 reads (11%) | called by mutect2, pindel, varscan2
- HNRNPD | c.344A>T p.D115V | Missense Mutation (SNP) | VAF 134/291 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- IGHV2-70 | c.191A>C p.K64T | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, varscan2
- IGHV2-70D | c.110T>G p.L37R | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, varscan2
- IGLV3-1 | c.40T>A p.C14S | Missense Mutation (SNP) | VAF 88/186 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- IL1R2 | c.790A>T p.T264S | Missense Mutation (SNP) | VAF 66/136 reads (49%) | SIFT tolerated (0.62); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- KRT1 | c.552C>G p.I184M | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MED19 | c.258C>A p.H86Q | Missense Mutation (SNP) | VAF 64/224 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- MYH2 | c.4756G>A p.D1586N | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- OR8U1 | c.281T>C p.F94S | Missense Mutation (SNP) | VAF 56/196 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- PTER | c.48G>T p.E16D | Missense Mutation (SNP) | VAF 119/306 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RFPL4B | c.511A>G p.S171G | Missense Mutation (SNP) | VAF 5/110 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.348); called by muse, mutect2
- RUSC2 | c.1456C>T p.P486S | Missense Mutation (SNP) | VAF 28/341 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SEMA3D | c.1546-2A>G p.X516_splice | Splice Site (SNP) | VAF 81/189 reads (43%) | called by muse, mutect2, varscan2
- SP1 | c.523G>C p.V175L (on ENST00000327443 / NM_138473.3; = p.V168L on NM_003109.1) | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- ST3GAL2 | c.958T>C p.F320L | Missense Mutation (SNP) | VAF 33/92 reads (36%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBTD1 | c.346C>A p.P116T | Missense Mutation (SNP) | VAF 13/183 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- UTP20 | c.2393G>A p.G798E | Missense Mutation (SNP) | VAF 9/148 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.338); called by muse, mutect2
- VEZT | c.549A>T p.R183S | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.239); called by muse, mutect2
- ZFHX4 | c.4070T>C p.V1357A | Missense Mutation (SNP) | VAF 105/205 reads (51%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF468 | c.1159G>T p.E387* | Nonsense Mutation (SNP) | VAF 71/259 reads (27%) | called by muse, mutect2, varscan2
- ADAMTS16 | c.1911T>C p.S637= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as rs1398153011; called by muse, mutect2, varscan2
- AMOTL1 | c.732G>A p.A244= | Silent (SNP) | VAF 63/166 reads (38%) | catalogued as rs374984236, COSV54414096; called by muse, mutect2, varscan2
- BRD8 | c.915C>T p.S305= (on ENST00000254900 / NM_139199.2; = p.S378= on NM_006696.4) | Silent (SNP) | VAF 44/146 reads (30%) | called by muse, mutect2, varscan2
- CD8B2 | c.378C>T p.F126= | Silent (SNP) | VAF 42/96 reads (44%) | catalogued as rs1471331952; called by muse, mutect2, varscan2
- CDH23 | c.870C>T p.S290= | Silent (SNP) | VAF 88/205 reads (43%) | catalogued as rs375292899; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- FRY | c.7731T>C p.D2577= | Silent (SNP) | VAF 149/149 reads (100%) | called by muse, mutect2, varscan2
- GRIP2 | c.1848G>A p.G616= (on ENST00000619221; = p.G519= on NM_001080423.4) | Silent (SNP) | VAF 23/113 reads (20%) | catalogued as COSV56121631; called by muse, mutect2, varscan2
- HECTD4 | c.13059C>T p.D4353= | Silent (SNP) | VAF 8/152 reads (5%) | called by muse, mutect2
- IGHD2-8 | c.9G>A p.L3= | Silent (SNP) | VAF 57/58 reads (98%) | called by muse, mutect2, varscan2
- IGHV2-70D | c.339G>C p.T113= | Silent (SNP) | VAF 21/44 reads (48%) | called by muse, varscan2
- IGLL5 | c.51C>G p.G17= | Silent (SNP) | VAF 24/49 reads (49%) | catalogued as rs1176686017; called by muse, mutect2, varscan2
- IGLL5 | c.171A>G p.G57= | Silent (SNP) | VAF 15/26 reads (58%) | catalogued as rs115653109, COSV101597202; called by muse, mutect2, varscan2
- IGLV3-9 | c.42T>C p.F14= | Silent (SNP) | VAF 38/88 reads (43%) | catalogued as rs775097231; called by muse, mutect2, varscan2
- MAB21L4 | c.987C>T p.L329= (on ENST00000388934 / NM_001085437.3; = p.L161= on NM_024861.4) | Silent (SNP) | VAF 44/108 reads (41%) | catalogued as rs1032602355; called by muse, mutect2, varscan2
- OR4K14 | c.750G>T p.L250= | Silent (SNP) | VAF 21/117 reads (18%) | called by muse, mutect2, varscan2
- PALM2AKAP2 | c.453C>T p.T151= (on ENST00000374531 / NM_001037293.2; = p.T183= on NM_053016.6) | Silent (SNP) | VAF 66/215 reads (31%) | called by muse, mutect2, varscan2
- PKHD1 | c.210C>T p.P70= | Silent (SNP) | VAF 62/119 reads (52%) | catalogued as rs372103359, COSV100580947; called by muse, mutect2, varscan2
- PUS10 | c.1320C>T p.I440= | Silent (SNP) | VAF 10/171 reads (6%) | catalogued as COSV57455408; called by muse, mutect2
- RIPOR3 | c.189G>A p.G63= | Silent (SNP) | VAF 62/111 reads (56%) | called by muse, mutect2, varscan2
- TNFRSF19 | c.642C>T p.N214= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs751482871; called by muse, mutect2, varscan2
- AC124067.2 | n.141-32A>C | Intron (SNP) | VAF 92/156 reads (59%) | called by muse, mutect2, varscan2
- C16orf72 | c.*584A>G | 3'UTR (SNP) | VAF 47/87 reads (54%) | called by muse, mutect2, varscan2
- C16orf90 | c.*106C>T | 3'UTR (SNP) | VAF 78/151 reads (52%) | called by muse, mutect2, varscan2
- C1orf158 | c.*1795C>A | 3'UTR (SNP) | VAF 25/48 reads (52%) | catalogued as COSV55346417; called by muse, mutect2, varscan2
- DPH2 | c.260+94C>T | Intron (SNP) | VAF 12/250 reads (5%) | catalogued as rs931204152; called by muse, mutect2
- DSCC1 | c.-16T>C | 5'UTR (SNP) | VAF 34/71 reads (48%) | called by muse, mutect2, varscan2
- EIF4A2 | c.627+27_627+30del | Intron (DEL) | VAF 9/28 reads (32%) | called by mutect2, pindel, varscan2
- EML1 | c.-11T>G | 5'UTR (SNP) | VAF 39/83 reads (47%) | called by muse, mutect2, varscan2
- FAF2 | chr5:176447852 G>C | 5'Flank (SNP) | VAF 120/342 reads (35%) | called by muse, mutect2, varscan2
- FAM160A1 | c.*745T>G | 3'UTR (SNP) | VAF 33/55 reads (60%) | catalogued as rs1021508522; called by muse, mutect2, varscan2
- FBN1 | c.*1509T>G | 3'UTR (SNP) | VAF 39/122 reads (32%) | called by muse, mutect2, varscan2
- FNBP1 | c.*1859T>C | 3'UTR (SNP) | VAF 160/261 reads (61%) | called by muse, mutect2, varscan2
- GXYLT1 | c.*3078T>G | 3'UTR (SNP) | VAF 15/41 reads (37%) | called by muse, mutect2
- HEPACAM | c.709+33C>A | Intron (SNP) | VAF 15/82 reads (18%) | called by muse, mutect2, varscan2
- IL1R1 | c.840-8_840-7dup | Intron (INS) | VAF 26/52 reads (50%) | called by mutect2, varscan2
- JMJD8 | c.*96C>T | 3'UTR (SNP) | VAF 66/125 reads (53%) | called by muse, mutect2, varscan2
- JUP | c.*49G>A | 3'UTR (SNP) | VAF 25/125 reads (20%) | called by muse, mutect2, varscan2
- LNX1 | c.380+15436C>A | Intron (SNP) | VAF 16/67 reads (24%) | called by muse, mutect2, varscan2
- MAPK8IP2 | c.*592A>T | 3'UTR (SNP) | VAF 14/129 reads (11%) | called by muse, mutect2, varscan2
- MIER1 | c.*1623T>A | 3'UTR (SNP) | VAF 131/276 reads (47%) | called by muse, varscan2
- MMP16 | c.-38G>A | 5'UTR (SNP) | VAF 19/169 reads (11%) | called by muse, mutect2, varscan2
- MS4A1 | c.*1599T>G | 3'UTR (SNP) | VAF 26/113 reads (23%) | called by muse, mutect2, varscan2
- NDST3 | c.*90T>G | 3'UTR (SNP) | VAF 82/176 reads (47%) | called by muse, mutect2, varscan2
- NFIB | chr9:14314502 T>C | 5'Flank (SNP) | VAF 117/163 reads (72%) | catalogued as rs557868888; called by muse, mutect2, varscan2
- NR2C2 | c.1510+104T>C | Intron (SNP) | VAF 12/108 reads (11%) | catalogued as rs545392080; called by muse, mutect2
- NRXN3 | c.*168A>G | 3'UTR (SNP) | VAF 42/98 reads (43%) | called by muse, mutect2, varscan2
- NUB1 | c.872+113T>C | Intron (SNP) | VAF 36/85 reads (42%) | called by muse, mutect2, varscan2
- OR5M11 | c.*36T>G | 3'UTR (SNP) | VAF 175/541 reads (32%) | called by muse, mutect2, varscan2
- OTULIN | c.*4637C>T | 3'UTR (SNP) | VAF 11/51 reads (22%) | called by muse, mutect2, varscan2
- PCDHAC1 | c.*1529T>A | 3'UTR (SNP) | VAF 30/106 reads (28%) | called by muse, mutect2, varscan2
- PIK3CG | chr7:106907272 C>G | 3'Flank (SNP) | VAF 9/19 reads (47%) | called by muse, mutect2, varscan2
- PLEC | c.*675G>A | 3'UTR (SNP) | VAF 8/71 reads (11%) | called by mutect2, varscan2
- PSG6 | chr19:42917838 A>T | 5'Flank (SNP) | VAF 29/289 reads (10%) | catalogued as rs866223100; called by muse, mutect2, varscan2
- RAX | c.*1657G>A | 3'UTR (SNP) | VAF 59/125 reads (47%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159565 C>A | 5'Flank (SNP) | VAF 3/15 reads (20%) | called by muse, mutect2
- SAXO1 | c.*363G>A | 3'UTR (SNP) | VAF 63/114 reads (55%) | catalogued as rs1022283709; called by muse, mutect2, varscan2
- SGMS2 | chr4:107914004 T>G | 3'Flank (SNP) | VAF 41/97 reads (42%) | called by muse, mutect2, varscan2
- SH2D1B | c.*1665T>C | 3'UTR (SNP) | VAF 4/98 reads (4%) | called by muse, mutect2
- SLC27A6 | c.*341A>C | 3'UTR (SNP) | VAF 22/54 reads (41%) | called by muse, mutect2, varscan2
- SOX11 | c.*3995A>T | 3'UTR (SNP) | VAF 6/72 reads (8%) | catalogued as COSV58983565; called by muse, mutect2
- SPTA1 | c.-132T>C | 5'UTR (SNP) | VAF 117/254 reads (46%) | called by muse, mutect2, varscan2
- SRSF5 | c.367-52T>A | Intron (SNP) | VAF 3/15 reads (20%) | called by muse, mutect2
- SSC5D | c.*14T>A | 3'UTR (SNP) | VAF 8/156 reads (5%) | called by muse, mutect2
- SSH1 | c.*3179dup | 3'UTR (INS) | VAF 42/105 reads (40%) | called by mutect2, pindel, varscan2
- TMEM40 | chr3:12734606 C>T | 3'Flank (SNP) | VAF 70/235 reads (30%) | called by muse, mutect2, varscan2
- UNC45B | c.*1386A>C | 3'UTR (SNP) | VAF 24/63 reads (38%) | called by muse, mutect2, varscan2
- YKT6 | c.*1544C>A | 3'UTR (SNP) | VAF 82/192 reads (43%) | called by muse, mutect2, varscan2
